Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7425, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7425-01A (Primary Tumor).

[page 1 of 2]
SUPPLEMENTAL REPORT

DIAGNOSIS:

BONE FROM MAXILLARY SINUS:

MINUTE FRAGMENT OF BONE AND FOCI OF SQUAMOUS CARCINOMA.

DIAGNOSIS

- (A) TUMOR HARD PALATE:
INVASIVE WELL-DIFFERENTIATED SQUAMOUS CELL CARCINOMA INVOLVING BONE.
- (B) MAXILLARY SINUS:
FRAGMENTS OF INVASIVE WELL-DIFFERENTIATED SQUAMOUS CELL CARCINOMA.
- (C) BONE FROM MAXILLARY SINUS:
Pending decalcification.
- (D) TISSUE FROM LATERAL SIDE OF PALATE:
Salivary gland, no tumor present.
- (E) MUCOSA RIGHT MAXILLARY SINUS:
INVASIVE WELL-DIFFERENTIATED SQUAMOUS CELL CARCINOMA.
Respiratory mucosa, no tumor present.
- PARTIAL MAXILLECTOMY:**
INVASIVE WELL-DIFFERENTIATED SQUAMOUS CELL CARCINOMA.

GROSS DESCRIPTION

- (A) TUMOR HARD PALATE - Multiple fragments of tan soft tissue 2.0 x 1.5 x 0.5 cm. Submitted in toto in A1 and A2.
- (B) TUMOR FROM MAXILLARY SINUS - Multiple fragments of tan soft tissue 1.5 x 1.0 x 0.5 cm in aggregate. Submitted in toto in B.
- (C) BONE FROM MAXILLARY SINUS - Multiple fragments of bone 0.8 x 0.8 x 0.2 cm

[page 2 of 2]
in aggregate. Submitted in toto in C pending for decalcification. [REDACTED]
(D) TISSUE FROM LATERAL SIDE OF PALATE - Two fragments of tan soft tissue 0.6 and 0.8 cm in greatest dimension. Submitted in toto in D. [REDACTED]
(E) MUCOSA MAXILLARY SINUS - Multiple fragments of tan soft tissue 0.8 x 0.6 x 0.2 cm in aggregate. Submitted in toto in E. [REDACTED]
(F) PARTIAL MAXILLECTOMY - A partial maxillectomy specimen 5.0 x 2.0 cm to the depth of 2.0 cm with attached three teeth anterior. The specimen is oriented by the surgeon.

At the center of the specimen there is an exophytic tan-soft mass 3.0 x 2.8 x 1.2 cm. The mass extends to the base of the specimen. The mass is 0.1 cm from lateral margin, 0.2 cm from medial margin, 0.5 cm from posterior margin and 1.3 cm from anterior margin.

Fragments of bone are noted at base of specimen.

INK CODE: Yellow-anterior; blue-posterior, green-left half of specimen, red-medial half of specimen.

SECTION CODE: F1, posterior margin en face; F2-F4, tumor with deep margin perpendicular (F4, contains bone fragment pending for decalcification); F5, F6, more tumor; F7, anterior margin en face. Remaining bone fragments sent to Bone Lab for further processing. [REDACTED]

SNOMED CODES

M-80703 T-11170 T-22000 T-51100

Source: NCI Genomic Data Commons file ef84a42e-9cf5-405b-8ca8-0396a6ab419b (TCGA-CV-7425.F48CCA43-8576-40A3-868B-BAF5753A94F6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).